Somatic mutation profile of tumor specimen TCGA-CV-7568-01A (aliquot TCGA-CV-7568-01A-11D-2229-08) from TCGA case TCGA-CV-7568, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 48.4 years (17,670 days).
Specimen TCGA-CV-7568-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a8d9ecc-9316-4988-9ce8-254f1c2e0255.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7568-10A (Blood Derived Normal), aliquot TCGA-CV-7568-10A-01D-2229-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60a32974-f41b-4c4a-99ae-91f908bc9c0d

The open-access MAF lists 2,787 somatic variants for this specimen: 1,827 protein-altering or splice-affecting, 905 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,658, Silent 905, Nonsense Mutation 110, Splice Site 29, Splice Region 22, Intron 22, RNA 18, 5'Flank 6, 3'Flank 6, 3'UTR 3, Frame Shift Del 3, Translation Start Site 3.

Variants (750 of 2,787; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 11/16 reads (69%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.665); catalogued as CM034218, CM095540, COSV58683071, COSV58683670; called by muse, mutect2, varscan2
- DSP | c.1873C>T p.Q625* | Nonsense Mutation (SNP) | VAF 49/74 reads (66%) | catalogued as rs876657638, CM114455, COSV101131165; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- OXA1L | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 66/174 reads (38%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.11); PolyPhen benign (0.208); catalogued as rs773412250, COSV53536555; called by muse, mutect2, varscan2
- PIK3CA | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 23/72 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs863225060, COSV55878075, COSV55925758; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as rs118192160, CM061939, CM140861, COSV62087706, COSV62099686; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.2995G>A p.E999K | Missense Mutation (SNP) | VAF 89/232 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs796053126, CM139611, COSV51835030; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 27/33 reads (82%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A1BG | c.820G>A p.G274R | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.223); catalogued as rs1381759220, COSV99568765; called by muse, varscan2
- A1CF | c.1283G>A p.G428E (on ENST00000373993 / NM_138932.2; = p.G420E on NM_014576.4) | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1404517565, COSV50958219; called by muse, varscan2
- A2M | c.2138T>A p.M713K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100589082, COSV59385043; called by muse, mutect2, varscan2
- AACS | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 54/283 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as COSV99908329; called by muse, mutect2, varscan2
- AACS | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs376649709, COSV99908330; called by muse, mutect2, varscan2
- AASS | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); catalogued as rs759258946, COSV100741645; called by muse, mutect2, varscan2
- ABCA7 | c.2267C>T p.P756L | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV99566787; called by muse, mutect2, varscan2
- ABCA9 | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as rs1467605143, COSV60623733; called by muse, mutect2, varscan2
- ABCC1 | c.3430G>A p.E1144K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1264102348, COSV60685214; called by muse, mutect2, varscan2
- ABCC1 | c.3662C>T p.S1221F | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100580495; called by muse, mutect2, varscan2
- ABCC4 | c.2450C>T p.P817L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100972874; called by muse, mutect2, varscan2
- ABCC4 | c.2449C>T p.P817S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.901); catalogued as COSV100972877; called by muse, mutect2, varscan2
- ABCC8 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV100217811, COSV56855068; called by muse, mutect2, varscan2
- ABHD16A | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV101013391; called by muse, mutect2, varscan2
- ABHD18 | c.1172C>T p.P391L (on ENST00000398965 / NM_001039717.2; = p.P298L on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101180908; called by muse, mutect2, varscan2
- ABLIM1 | c.1685C>T p.P562L | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.065); catalogued as COSV99522862; called by muse, mutect2, varscan2
- ABRA | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as rs149782926, COSV100357675; called by muse, mutect2, varscan2
- ABRA | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.714); catalogued as rs1264911183, COSV100357681; called by muse, mutect2, varscan2
- AC011448.1 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); catalogued as rs568922370, COSV99365303; called by muse, mutect2, varscan2
- AC011448.1 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (1); PolyPhen possibly damaging (0.542); catalogued as rs750758891, COSV99365305; called by muse, mutect2, varscan2
- AC109583.1 | c.471G>A p.W157* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as rs1204004478, COSV100168002; called by muse, mutect2, varscan2
- AC136428.1 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV101434982, COSV101434991; called by muse, mutect2, varscan2
- AC244197.3 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.124); catalogued as COSV100558222; called by muse, mutect2, varscan2
- AC244197.3 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV100558223, COSV61712818; called by muse, mutect2, varscan2
- ACACB | c.5530A>G p.M1844V | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV100623375; called by muse, mutect2, varscan2
- ACCSL | c.863A>G p.E288G | Missense Mutation (SNP) | VAF 73/183 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV101122331; called by muse, mutect2, varscan2
- ACD | c.184C>A p.L62I | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.207); catalogued as COSV54665920, COSV99538042; called by muse, mutect2, varscan2
- ACRBP | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV99976322; called by muse, mutect2, varscan2
- ACSM1 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.58); catalogued as rs753176879, COSV99533525; called by muse, mutect2, varscan2
- ACSM2A | c.1667G>A p.G556E (on ENST00000219054; = p.G477E on NM_001308169.2) | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99525813; called by muse, mutect2, varscan2
- ACTN1 | c.2407C>A p.R803S | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV99518602, COSV99518683; called by muse, mutect2, varscan2
- ACTRT1 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.48); catalogued as COSV100947790; called by muse, mutect2, varscan2
- ADAD1 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.177); catalogued as rs867796878, COSV56641957; called by muse, mutect2, varscan2
- ADAM10 | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV99546858; called by muse, mutect2, varscan2
- ADAM28 | c.860G>A p.R287K | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV99739760, COSV99740051; called by muse, mutect2, varscan2
- ADAM9 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.526); catalogued as COSV101122289; called by muse, mutect2, varscan2
- ADAMTS12 | c.4104G>C p.W1368C | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100711730, COSV61271087; called by muse, mutect2, varscan2
- ADAMTS18 | c.1474G>A p.G492R | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.116); catalogued as COSV99274547; called by muse, mutect2, varscan2
- ADAMTS4 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs745567847, COSV100917919; called by muse, mutect2, varscan2
- ADCK1 | c.967G>A p.G323R | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as COSV99452848; called by muse, mutect2
- ADCK2 | c.1847C>T p.P616L | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99200000; called by muse, mutect2, varscan2
- ADCY1 | c.2724G>A p.M908I | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.103); catalogued as COSV52039618, COSV99813071; called by muse, mutect2, varscan2
- ADCY1 | c.2834C>G p.S945C | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as COSV99813072; called by muse, mutect2, varscan2
- ADCY2 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as rs1167334638, COSV100604498; called by muse, mutect2, varscan2
- ADCY2 | c.2581C>T p.P861S | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100604500; called by muse, mutect2
- ADCY8 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV53912465, COSV99654794; called by muse, mutect2, varscan2
- ADGRA2 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868319164, COSV100178524; called by muse, mutect2, varscan2
- ADGRA2 | c.889C>T p.L297F | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.81); PolyPhen benign (0.009); catalogued as rs774514376, COSV59446343; called by muse, mutect2, varscan2
- ADGRE5 | c.1208C>T p.S403F (on ENST00000242786 / NM_078481.4; = p.S310F on NM_001784.5) | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV54409412; called by muse, mutect2, varscan2
- ADGRG2 | c.767C>T p.S256F (on ENST00000379869 / NM_001079858.3; = p.S253F on NM_005756.4) | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs1218959557, COSV100492812; called by muse, mutect2, varscan2
- ADGRV1 | c.10247G>A p.G3416E | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as rs1455003943, COSV67979348; called by muse, mutect2, varscan2
- ADGRV1 | c.15644C>T p.S5215F | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV67996191; called by muse, varscan2
- AFAP1L2 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs17852236, COSV100413157; called by muse, mutect2, varscan2
- AFMID | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100015137; called by muse, mutect2, varscan2
- AFMID | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.261); catalogued as COSV100015140; called by muse, mutect2, varscan2
- AHDC1 | c.1898C>T p.S633L | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99899829; called by muse, mutect2, varscan2
- AHNAK | c.11270C>T p.P3757L | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs551324364, COSV99946390; called by muse, mutect2, varscan2
- AKAP3 | c.1478C>T p.S493F | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV57417623; called by muse, mutect2, varscan2
- AKAP4 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100654389; called by muse, mutect2, varscan2
- AKR1A1 | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs199650864, COSV100698803; called by muse, mutect2, varscan2
- AL121899.2 | c.1298T>A p.V433E | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as COSV101198704; called by muse, varscan2
- AL645922.1 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 93/177 reads (53%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV100191565; called by muse, mutect2, varscan2
- AL645922.1 | c.2792G>A p.G931E | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100191568; called by muse, mutect2, varscan2
- ALB | c.1001T>C p.V334A | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.096); catalogued as COSV99892478; called by muse, mutect2, varscan2
- ALG13 | c.1486G>A p.G496R | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99323237; called by muse, mutect2, varscan2
- ALKAL1 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs145116532; called by muse, mutect2, varscan2
- ALLC | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 77/192 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99378364; called by muse, mutect2, varscan2
- ALX4 | c.488A>C p.E163A | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV100241367; called by muse, mutect2, varscan2
- AMMECR1 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as rs774068575, COSV99467281; called by muse, varscan2
- AMPH | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.116); catalogued as rs748822925, COSV57747270; called by muse, mutect2, varscan2
- AMPH | c.1218C>T p.P406= | Splice Region (SNP) | VAF 53/142 reads (37%) | catalogued as COSV100343954, COSV57743978; called by muse, mutect2, varscan2
- AMPH | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as COSV100343959, COSV57751863; called by muse, mutect2, varscan2
- AMY2A | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1316755105, COSV101340687; called by muse, mutect2, varscan2
- AMY2B | c.1316G>A p.R439K | Missense Mutation (SNP) | VAF 89/215 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100796277, COSV100796545; called by muse, mutect2, varscan2
- AMZ2 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs782541022, COSV100703256; called by muse, mutect2, varscan2
- ANGEL1 | c.1403C>T p.S468F | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV51874728; called by muse, mutect2, varscan2
- ANGPTL5 | c.306G>A p.M102I | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1302018101, COSV100528043; called by muse, mutect2, varscan2
- ANKAR | c.4093C>T p.Q1365* | Nonsense Mutation (SNP) | VAF 47/150 reads (31%) | catalogued as COSV99854794; called by muse, mutect2, varscan2
- ANKRD30A | c.1606A>G p.K536E (on ENST00000611781; = p.K480E on NM_052997.2) | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.899); catalogued as rs764427256, COSV100654576; called by muse, mutect2, varscan2
- ANKRD30A | c.3421G>A p.E1141K (on ENST00000611781; = p.E1085K on NM_052997.2) | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as COSV100654579, COSV64605169; called by muse, mutect2, varscan2
- ANKRD33 | c.193G>A p.G65R (on ENST00000340970 / NM_001304459.2; = p.G200R on NM_182608.4) | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56608357; called by muse, mutect2, varscan2
- ANKRD33 | c.304G>T p.A102S (on ENST00000340970 / NM_001304459.2; = p.A227S on NM_182608.4) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV56608273; called by muse, mutect2, varscan2
- ANOS1 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.951); catalogued as COSV99391589; called by muse, mutect2, varscan2
- ANXA11 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as rs1170082588, COSV99627607; called by muse, mutect2, varscan2
- ANXA3 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); catalogued as COSV99364015; called by muse, mutect2, varscan2
- AOC3 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1362918955, COSV99520474; called by muse, mutect2, varscan2
- AOC3 | c.2275G>A p.G759S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV57736040; called by muse, mutect2, varscan2
- AP3B2 | c.1874G>A p.G625D | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1196607606, COSV55609554, COSV99915901; called by muse, mutect2, varscan2
- AP5Z1 | c.1943G>A p.W648* | Nonsense Mutation (SNP) | VAF 20/33 reads (61%) | catalogued as rs768203919, COSV100804267; called by muse, mutect2, varscan2
- APBA2 | c.1350G>A p.M450I | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as COSV101258230; called by muse, mutect2, varscan2
- APBA2 | c.1351G>A p.D451N | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101258231; called by muse, mutect2, varscan2
- APC | c.4138A>C p.T1380P | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99970798; called by muse, mutect2, varscan2
- APOL3 | c.781G>A p.D261N (on ENST00000349314 / NM_145640.2; = p.D190N on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.048); catalogued as COSV100652184; called by muse, mutect2, varscan2
- APOL5 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs757147117, COSV99968491; called by muse, mutect2, varscan2
- ARAF | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99283490; called by muse, mutect2, varscan2
- ARAP3 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99499574; called by muse, mutect2, varscan2
- ARFGEF1 | c.3290-1G>A p.X1097_splice | Splice Site (SNP) | VAF 47/125 reads (38%) | catalogued as COSV99145430; called by muse, mutect2, varscan2
- ARG1 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV99256316; called by muse, mutect2, varscan2
- ARHGAP15 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV54495270, COSV99710380, COSV99714277; called by muse, mutect2, varscan2
- ARHGAP20 | c.1462C>T p.L488F | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99505659; called by muse, mutect2, varscan2
- ARHGAP21 | c.5030C>T p.T1677I | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.465); catalogued as rs553242970, COSV100256788; called by muse, mutect2, varscan2
- ARHGAP21 | c.2047C>T p.P683S | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs772276820, COSV100256792; called by muse, mutect2, varscan2
- ARHGAP29 | c.1636G>A p.G546R | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53114209; called by muse, mutect2, varscan2
- ARHGAP4 | c.1463T>A p.F488Y | Missense Mutation (SNP) | VAF 71/176 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.081); catalogued as COSV100604310; called by muse, mutect2, varscan2
- ARHGAP4 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.177); catalogued as rs782656080, COSV100604311; called by muse, mutect2, varscan2
- ARHGAP5 | c.3581G>A p.G1194E | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.412); catalogued as rs149893615; called by muse, mutect2, varscan2
- ARID1A | c.4451C>T p.P1484L | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV100253771; called by muse, mutect2, varscan2
- ARL6IP5 | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs918816761, COSV99833060; called by muse, mutect2, varscan2
- ARL8B | c.91T>C p.S31P | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99848871; called by muse, mutect2, varscan2
- ARMC4 | c.2861G>A p.R954K | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.029); catalogued as COSV100537495; called by muse, mutect2, varscan2
- ARMC7 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV55461924, COSV55461999; called by muse, mutect2, varscan2
- ARPP21 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); catalogued as COSV51792546; called by muse, mutect2, varscan2
- ARSD | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); catalogued as COSV99472457; called by muse, mutect2, varscan2
- ARSH | c.1672C>T p.L558F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.12); catalogued as COSV101140014; called by muse, varscan2
- ART1 | c.958T>A p.F320I | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV99167278; called by muse, mutect2, varscan2
- ASTE1 | c.1835G>A p.R612K | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1305548419, COSV99394045; called by muse, mutect2, varscan2
- ASXL3 | c.4678C>T p.R1560* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as rs199978752, COSV99326992; called by muse, mutect2, varscan2
- ATCAY | c.610C>T p.L204F | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.71); PolyPhen benign (0.389); catalogued as COSV100009090; called by muse, mutect2, varscan2
- ATG14 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV99903087; called by muse, mutect2, varscan2
- ATP10B | c.4361G>A p.R1454Q | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs534112987, COSV59145135, COSV59156028, COSV59162753; called by muse, mutect2, varscan2
- ATP11C | c.2996G>A p.G999E | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100558801; called by muse, mutect2, varscan2
- ATP2A2 | c.2294C>T p.S765L | Missense Mutation (SNP) | VAF 46/73 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM990252, COSV57875783; called by muse, mutect2, varscan2
- ATP2A2 | c.2747C>T p.S916F | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as CM011281, COSV57875459; called by muse, mutect2, varscan2
- ATP2B3 | c.3280G>A p.E1094K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs868971762, COSV54840322, COSV99683496; called by muse, mutect2, varscan2
- ATP5MC1 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs745820931, COSV100582440, COSV63506012; called by muse, mutect2, varscan2
- ATP7A | c.1684G>A p.G562R | Missense Mutation (SNP) | VAF 93/214 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as COSV100431885; called by muse, mutect2, varscan2
- ATP8A1 | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.244); catalogued as COSV100047510; called by muse, mutect2, varscan2
- ATP9B | c.3182C>T p.T1061I | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100304362; called by muse, mutect2, varscan2
- ATRX | c.4956+1G>A p.X1652_splice | Splice Site (SNP) | VAF 34/96 reads (35%) | catalogued as COSV100971595; called by muse, mutect2, varscan2
- ATRX | c.4956G>A p.E1652= | Splice Region (SNP) | VAF 34/96 reads (35%) | catalogued as COSV100971596; called by muse, mutect2, varscan2
- ATRX | c.3937G>A p.D1313N | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.747); catalogued as COSV100971597; called by muse, mutect2, varscan2
- ATRX | c.2342G>A p.R781Q | Missense Mutation (SNP) | VAF 132/261 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV64886569; called by muse, mutect2, varscan2
- AUTS2 | c.2203C>T p.L735F | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1480946986, COSV61398828; called by muse, mutect2, varscan2
- AVPR1B | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs868925962, COSV100899448, COSV65637750; called by muse, mutect2, varscan2
- AXIN1 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV99250425; called by muse, mutect2, varscan2
- BACH2 | c.2219C>T p.T740M | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT tolerated (0.1); PolyPhen benign (0.23); catalogued as rs878885096, COSV57596296; called by muse, mutect2, varscan2
- BBOF1 | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as COSV101223974; called by muse, mutect2, varscan2
- BBS7 | c.34C>T p.Q12* | Nonsense Mutation (SNP) | VAF 16/68 reads (24%) | catalogued as COSV99145169; called by muse, mutect2, varscan2
- BCAN | c.1241G>A p.G414E | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as rs949759031, COSV100228555; called by muse, mutect2, varscan2
- BCAP31 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV100799025; called by muse, mutect2, varscan2
- BCAS1 | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 85/236 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs773196382, COSV101006509; called by muse, mutect2, varscan2
- BCAS3 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 75/219 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV101177357; called by muse, mutect2, varscan2
- BCAT1 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99679127; called by muse, varscan2
- BCKDK | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs1314768565, COSV99570949; called by muse, mutect2
- BCL2L14 | c.410T>C p.V137A | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.197); catalogued as COSV99845297; called by muse, mutect2, varscan2
- BCO1 | c.1361G>A p.W454* | Nonsense Mutation (SNP) | VAF 32/96 reads (33%) | catalogued as COSV99258807; called by muse, mutect2, varscan2
- BCOR | c.3402G>C p.R1134S | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV100654328, COSV60706150; called by muse, mutect2, varscan2
- BCOR | c.1210C>T p.Q404* | Nonsense Mutation (SNP) | VAF 22/47 reads (47%) | catalogued as COSV100654331; called by muse, mutect2, varscan2
- BCORL1 | c.4470G>A p.T1490= | Splice Region (SNP) | VAF 37/108 reads (34%) | catalogued as rs1019925690, COSV54399197; called by muse, mutect2, varscan2
- BEND2 | c.2290G>A p.D764N | Missense Mutation (SNP) | VAF 114/263 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV101192717; called by muse, mutect2, varscan2
- BGN | c.904C>T p.L302F | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100525330; called by muse, mutect2, varscan2
- BIN1 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV52119417, COSV99388678; called by muse, mutect2
- BIRC6 | c.13975C>T p.L4659F | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70196229; called by muse, mutect2, varscan2
- BLM | c.2144C>T p.P715L | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61927430; called by muse, mutect2, varscan2
- BMP1 | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.741); catalogued as rs374904129, COSV100110240; called by muse, mutect2, varscan2
- BMP3 | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 72/125 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99261943; called by muse, mutect2, varscan2
- BMP3 | c.653G>A p.G218E | Missense Mutation (SNP) | VAF 74/127 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99261491; called by muse, mutect2, varscan2
- BMPER | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.383); catalogued as rs1228099396, COSV51814331; called by muse, mutect2, varscan2
- BPIFB3 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100972445; called by muse, mutect2
- BRD4 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); catalogued as COSV54592638, COSV99650879; called by muse, mutect2, varscan2
- BRD8 | c.1780G>A p.E594K (on ENST00000254900 / NM_139199.2; = p.E667K on NM_006696.4) | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV99137840; called by muse, mutect2, varscan2
- BRF2 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV55103364; called by muse, mutect2, varscan2
- BRINP3 | c.1788G>A p.W596* | Nonsense Mutation (SNP) | VAF 83/161 reads (52%) | catalogued as COSV100819596; called by muse, mutect2, varscan2
- BRSK1 | c.2162C>T p.S721F | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); catalogued as COSV100442510; called by muse, mutect2, varscan2
- BRWD3 | c.842G>A p.R281K | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as COSV100956639, COSV64745075; called by muse, mutect2, varscan2
- BSND | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.463); catalogued as COSV64870608; called by muse, mutect2, varscan2
- BTNL3 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.563); catalogued as COSV100732260; called by muse, mutect2, varscan2
- C10orf90 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as rs1312911946, COSV99505359; called by muse, varscan2
- C12orf45 | c.117T>G p.G39= | Splice Region (SNP) | VAF 15/19 reads (79%) | catalogued as COSV99774075; called by muse, mutect2, varscan2
- C15orf39 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV100641512; called by muse, mutect2, varscan2
- C17orf97 | c.449C>T p.T150I | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.488); catalogued as COSV100789400; called by muse, mutect2, varscan2
- C19orf57 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV100694882; called by muse, varscan2
- C19orf57 | c.1000C>T p.L334F | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.865); catalogued as rs1349140935, COSV100694676, COSV100694883; called by muse, mutect2, varscan2
- C1QA | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV101009564; called by muse, mutect2, varscan2
- C1QTNF9B | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1221459808, COSV101158611; called by muse, mutect2, varscan2
- C1orf146 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs192356914, COSV64860267; called by muse, mutect2, varscan2
- C2orf16 | c.2902G>A p.G968S | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.271); catalogued as COSV100821113; called by muse, mutect2, varscan2
- C2orf16 | c.2903G>A p.G968D | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.148); catalogued as rs1431765233, COSV100821115; called by muse, mutect2, varscan2
- C2orf80 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 41/53 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376481518, COSV100378714; called by muse, mutect2, varscan2
- C3AR1 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs1435871949, COSV99369094; called by muse, mutect2, varscan2
- C3orf22 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1270856459, COSV100559561; called by muse, mutect2
- C6orf118 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100025281; called by muse, mutect2, varscan2
- C7 | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57473170; called by muse, mutect2, varscan2
- C7 | c.2479G>A p.G827R | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV57479422; called by muse, mutect2, varscan2
- C8B | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV64779151; called by muse, mutect2
- C8orf34 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV57410813; called by muse, mutect2, varscan2
- C8orf74 | c.848G>C p.R283T | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as COSV100262485; called by muse, mutect2
- CA14 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV99354568; called by muse, mutect2, varscan2
- CABP5 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99506768; called by muse, mutect2, varscan2
- CACNA1B | c.6746C>T p.A2249V | Missense Mutation (SNP) | VAF 39/57 reads (68%) | SIFT tolerated (0.15); PolyPhen benign (0.391); catalogued as COSV99500422; called by muse, mutect2, varscan2
- CACNA1D | c.3578C>T p.P1193L (on ENST00000350061 / NM_001128840.3; = p.P1213L on NM_000720.4) | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV55448488; called by muse, mutect2, varscan2
- CACNA1F | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100545490; called by muse, mutect2, varscan2
- CACNA1S | c.2203C>T p.P735S | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.743); catalogued as COSV100755448; called by muse, mutect2, varscan2
- CACNA2D4 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV54947241; called by muse, mutect2, varscan2
- CACUL1 | c.1003C>T p.L335F | Missense Mutation (SNP) | VAF 77/171 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100432771; called by muse, mutect2, varscan2
- CACYBP | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.067); catalogued as rs11548912, COSV100871649; called by muse, mutect2, varscan2
- CADM1 | c.1286G>A p.G429E | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59016915, COSV59017172; called by muse, mutect2, varscan2
- CADM2 | c.540G>C p.K180N (on ENST00000407528 / NM_001167674.2; = p.K182N on NM_153184.4) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV101059763; called by muse, mutect2, varscan2
- CADPS | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51911060; called by muse, mutect2, varscan2
- CADPS2 | c.2738G>A p.R913Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs866025011, COSV100466546; called by muse, varscan2
- CALN1 | c.106G>A p.E36K (on ENST00000329008 / NM_001017440.3; = p.E78K on NM_031468.4) | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV61131623; called by muse, mutect2, varscan2
- CAPN11 | c.784C>T p.L262F | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV101291977; called by muse, mutect2, varscan2
- CAPN6 | c.975G>T p.M325I | Missense Mutation (SNP) | VAF 135/379 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); catalogued as COSV60697261; called by muse, varscan2
- CARNMT1 | c.500G>A p.R167K | Missense Mutation (SNP) | VAF 103/140 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100961133; called by muse, mutect2, varscan2
- CASP3 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.962); catalogued as COSV100395107; called by muse, mutect2, varscan2
- CASR | c.1318G>A p.G440R | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as COSV99949569; called by muse, mutect2, varscan2
- CATSPERD | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.233); catalogued as COSV58464259; called by muse, mutect2, varscan2
- CBLB | c.74T>A p.I25N | Missense Mutation (SNP) | VAF 71/146 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV99914580; called by muse, mutect2, varscan2
- CBX1 | c.500G>A p.R167K | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV56682552; called by muse, mutect2, varscan2
- CBX6 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99328302; called by muse, mutect2, varscan2
- CC2D1A | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs773170398, COSV100528760; called by muse, varscan2
- CCDC105 | c.639G>A p.M213I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV99480167; called by muse, mutect2, varscan2
- CCDC160 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as COSV66251654; called by muse, mutect2, varscan2
- CCDC190 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV100905847; called by muse, mutect2, varscan2
- CCDC33 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.189); catalogued as rs767493515, COSV100351960; called by muse, mutect2, varscan2
- CCDC43 | c.520C>T p.L174F | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV100189100; called by muse, mutect2, varscan2
- CCDC80 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52816669; called by muse, mutect2, varscan2
- CCDC85A | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.097); catalogued as rs376208875, COSV101339600; called by muse, mutect2, varscan2
- CCL24 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1344147507, COSV56116449; called by muse, mutect2, varscan2
- CCNL2 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs764289996, COSV101275758; called by muse, mutect2, varscan2
- CCR4 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.227); catalogued as COSV100447556; called by muse, mutect2, varscan2
- CCR9 | c.475G>A p.E159K (on ENST00000357632 / NM_031200.3; = p.E147K on NM_006641.4) | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV62940957; called by muse, mutect2, varscan2
- CD163 | c.3260G>A p.G1087E | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.895); catalogued as COSV100776184; called by muse, mutect2, varscan2
- CD163 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV63133589; called by muse, mutect2, varscan2
- CD200R1L | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs752120624, COSV101236664; called by muse, mutect2, varscan2
- CD22 | c.2243C>T p.S748F | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs780466892, COSV50050051; called by muse, mutect2, varscan2
- CD2BP2 | c.852A>T p.E284D | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99977274; called by muse, mutect2, varscan2
- CD300E | c.539T>G p.L180R | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100151572; called by muse, mutect2
- CD38 | c.545A>G p.N182S | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV56889076; called by muse, mutect2, varscan2
- CD5 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs770948807, COSV61718147; called by muse, mutect2, varscan2
- CD74 | c.818-1G>A p.X273_splice (on ENST00000009530 / NM_001025159.2; = p.X209_splice on NM_004355.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 52/131 reads (40%) | catalogued as COSV99154451; called by muse, mutect2, varscan2
- CD79A | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs1555843453, COSV99702125; called by muse, mutect2, varscan2
- CD93 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as COSV99849689; called by muse, mutect2, varscan2
- CDC34 | c.345C>A p.N115K | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99296456; called by muse, varscan2
- CDC34 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53117330; called by muse, varscan2
- CDC34 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99296458; called by muse, varscan2
- CDH10 | c.2125G>A p.D709N | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.38); catalogued as COSV100053421; called by muse, varscan2
- CDH10 | c.2099G>A p.R700K | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.05); catalogued as COSV100053425; called by muse, varscan2
- CDH10 | c.647G>A p.G216D | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100053426; called by muse, mutect2, varscan2
- CDH10 | c.647-1G>A p.X216_splice | Splice Site (SNP) | VAF 17/54 reads (31%) | catalogued as COSV100052695, COSV100053427; called by muse, mutect2, varscan2
- CDH13 | c.404G>A p.R135K | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99232004; called by muse, mutect2, varscan2
- CDH18 | c.2293C>T p.H765Y | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as COSV99938887; called by muse, mutect2, varscan2
- CDH23 | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.562); catalogued as COSV54943698; called by muse, mutect2, varscan2
- CDH4 | c.1513C>T p.P505S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100849808; called by muse, mutect2, varscan2
- CDH4 | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100849809; called by muse, mutect2, varscan2
- CDH5 | c.1061G>A p.G354E | Missense Mutation (SNP) | VAF 70/184 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.071); catalogued as COSV58518369; called by muse, mutect2, varscan2
- CDH9 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs1419138258, COSV50251518, COSV50378157; called by muse, mutect2, varscan2
- CDHR1 | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV100259438; called by muse, mutect2, varscan2
- CDHR5 | c.1742G>A p.G581E (on ENST00000358353 / NM_001171968.2; = p.G587E on NM_021924.5) | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.876); catalogued as rs769489348, COSV100363888; called by muse, mutect2, varscan2
- CDK1 | c.813T>G p.D271E | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.332); catalogued as COSV100358929; called by muse, mutect2, varscan2
- CDK15 | c.418G>A p.E140K (on ENST00000652192 / NM_001366386.2; = p.E89K on NM_139158.2) | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53640173; called by muse, mutect2, varscan2
- CDK5 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs374928837; called by muse, mutect2, varscan2
- CDON | c.1555C>T p.P519S | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as rs776668606, COSV99702018; called by muse, mutect2, varscan2
- CEACAM18 | c.759G>A p.M253I | Missense Mutation (SNP) | VAF 77/206 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.108); catalogued as COSV101140772; called by muse, mutect2, varscan2
- CEACAM7 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.169); catalogued as rs1049234, COSV50073628; called by muse, mutect2, varscan2
- CEP164 | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as rs1036349313, COSV99634633; called by muse, mutect2, varscan2
- CEP170B | c.2578C>T p.P860S (on ENST00000453495; = p.P789S on NM_015005.3) | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as rs1170552448, COSV101371625; called by muse, mutect2, varscan2
- CEP192 | c.4537G>A p.G1513R | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100382313; called by muse, mutect2, varscan2
- CEP192 | c.4538G>A p.G1513E | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.681); catalogued as COSV100382320; called by muse, mutect2, varscan2
- CEP76 | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs751088597, COSV100043052; called by muse, mutect2, varscan2
- CERCAM | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs778706859, COSV100864133; called by muse, mutect2, varscan2
- CES1 | c.1045G>A p.G349R | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757978769, COSV62090579; called by muse, mutect2, varscan2
- CFAP221 | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 24/72 reads (33%) | catalogued as rs752357355, COSV54654594, COSV99733007; called by muse, mutect2, varscan2
- CFAP221 | c.2009C>T p.P670L | Missense Mutation (SNP) | VAF 80/209 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99733288; called by muse, mutect2, varscan2
- CFAP52 | c.1310G>A p.G437E | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.973); catalogued as COSV100235674; called by muse, mutect2, varscan2
- CFAP61 | c.1303C>T p.Q435* | Nonsense Mutation (SNP) | VAF 26/79 reads (33%) | catalogued as COSV99846938; called by muse, mutect2, varscan2
- CFAP61 | c.2096C>T p.S699L | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99846941; called by muse, mutect2, varscan2
- CGN | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV99642956; called by muse, mutect2, varscan2
- CHAF1B | c.1384G>A p.G462R | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100023600; called by muse, mutect2, varscan2
- CHD2 | c.944C>G p.S315C | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1275848961, COSV100560957; called by muse, mutect2, varscan2
- CHD9 | c.7085A>G p.Q2362R (on ENST00000398510 / NM_001382353.1; = p.Q2346R on NM_025134.7) | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); catalogued as COSV99529875; called by muse, mutect2, varscan2
- CHDH | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100179922; called by muse, mutect2, varscan2
- CHGB | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV100973148; called by muse, mutect2, varscan2
- CHIA | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.046); catalogued as rs375891484, COSV58477028; called by muse, mutect2
- CHRDL2 | c.753C>T p.A251= | Splice Region (SNP) | VAF 9/19 reads (47%) | catalogued as rs1408958571, COSV99734167; called by muse, mutect2, varscan2
- CHRM2 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV57769642; called by muse, mutect2, varscan2
- CHRM3 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.061); catalogued as rs768152496, COSV55085839; called by muse, mutect2, varscan2
- CHST1 | c.1195G>A p.V399I | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100346574, COSV57326481; called by muse, mutect2, varscan2
- CIAO3 | c.1192+1G>A p.X398_splice | Splice Site (SNP) | VAF 31/75 reads (41%) | catalogued as COSV99285239; called by muse, mutect2, varscan2
- CIITA | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.837); catalogued as rs1247007918, COSV100162694; called by muse, varscan2
- CIITA | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as COSV100162700; called by muse, mutect2, varscan2
- CLBA1 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs1364314445, COSV101121145; called by muse, mutect2, varscan2
- CLCNKB | c.2016G>A p.E672= | Splice Region (SNP) | VAF 62/137 reads (45%) | catalogued as COSV100989792; called by muse, mutect2, varscan2
- CLCNKB | c.2016+1G>A p.X672_splice | Splice Site (SNP) | VAF 61/134 reads (46%) | catalogued as rs1348712210, COSV65153352; called by muse, mutect2, varscan2
- CLDN17 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99729474; called by muse, mutect2, varscan2
- CLEC4G | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as COSV100183739; called by muse, mutect2, varscan2
- CLEC5A | c.345G>A p.L115= | Splice Region (SNP) | VAF 58/122 reads (48%) | catalogued as rs1554440998, COSV101407807; called by muse, mutect2, varscan2
- CLGN | c.1616A>G p.E539G | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as COSV100346875, COSV57774189; called by muse, mutect2, varscan2
- CLIP3 | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV99431354; called by muse, mutect2, varscan2
- CLMN | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs774934404, COSV54184777; called by muse, mutect2, varscan2
- CLTC | c.3868T>G p.Y1290D | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99293038; called by muse, mutect2, varscan2
- CLVS1 | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.27); catalogued as COSV100370801; called by muse, mutect2, varscan2
- CMTM5 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV100198230; called by muse, mutect2, varscan2
- CNDP1 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100722570; called by muse, mutect2, varscan2
- CNGA3 | c.106C>T p.H36Y | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.062); catalogued as rs1053293800, COSV99737661, COSV99737701; called by muse, mutect2, varscan2
- CNGB3 | c.2137G>A p.G713R | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV100183249; called by muse, mutect2, varscan2
- CNKSR2 | c.1478G>A p.G493E | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.422); catalogued as COSV99670105; called by muse, mutect2, varscan2
- CNKSR2 | c.1805C>T p.S602F | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99670110; called by muse, mutect2, varscan2
- CNKSR2 | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.255); catalogued as rs1442355363, COSV54264462; called by muse, mutect2, varscan2
- CNTN5 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.486); catalogued as rs1489941088, COSV54278175; called by muse, mutect2, varscan2
- CNTN6 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.998); catalogued as rs766274114, COSV100611985; called by muse, mutect2, varscan2
- CNTN6 | c.1541G>A p.G514D | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100611986; called by muse, mutect2, varscan2
- COIL | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV53596080; called by muse, mutect2, varscan2
- COL11A1 | c.3091G>A p.E1031K | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.079); catalogued as COSV62196469; called by muse, mutect2, varscan2
- COL11A1 | c.2488C>T p.Q830* | Nonsense Mutation (SNP) | VAF 17/66 reads (26%) | catalogued as COSV62185027; called by muse, mutect2, varscan2
- COL11A1 | c.1370G>A p.G457D | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs746336238, COSV100618282; called by muse, mutect2, varscan2
- COL11A1 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100618010, COSV62179153, COSV62185194; called by muse, varscan2
- COL11A1 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV62190291; called by muse, varscan2
- COL15A1 | c.1693G>A p.G565R | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.554); catalogued as COSV100898059, COSV66647423; called by muse, mutect2, varscan2
- COL15A1 | c.2658G>T p.M886I | Missense Mutation (SNP) | VAF 43/53 reads (81%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100898060; called by muse, mutect2, varscan2
- COL17A1 | c.2554G>A p.V852I | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs1459687091, COSV100793411; called by muse, mutect2, varscan2
- COL19A1 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.003); catalogued as rs1428949686, COSV100507713; called by muse, mutect2
- COL19A1 | c.2270T>G p.I757R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.522); catalogued as COSV100507714; called by muse, mutect2, varscan2
- COL1A2 | c.2626C>T p.P876S | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs762242102, COSV51955659; called by muse, mutect2, varscan2
- COL22A1 | c.4255C>T p.P1419S | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs868144647, COSV57337356; called by muse, mutect2, varscan2
- COL24A1 | c.1420T>G p.Y474D | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.669); catalogued as COSV100994143, COSV65301312; called by muse, mutect2, varscan2
- COL25A1 | c.1874G>A p.G625E | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67655733; called by muse, mutect2, varscan2
- COL27A1 | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 38/49 reads (78%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100621391; called by muse, mutect2, varscan2
- COL28A1 | c.1715G>A p.G572E | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101259001; called by muse, mutect2, varscan2
- COL4A2 | c.3101G>A p.G1034E | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100847520; called by muse, mutect2, varscan2
- COL4A3 | c.3248G>A p.G1083E | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59258539; called by muse, mutect2, varscan2
- COL4A5 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.722); catalogued as COSV100090424; called by muse, mutect2, varscan2
- COL4A5 | c.1250C>T p.S417F | Missense Mutation (SNP) | VAF 74/143 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV60372025; called by muse, mutect2, varscan2
- COL4A5 | c.3860C>T p.P1287L | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs1397121500, COSV100090428; called by muse, mutect2, varscan2
- COL4A6 | c.1898C>T p.P633L | Missense Mutation (SNP) | VAF 204/452 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100564911; called by muse, mutect2, varscan2
- COL5A1 | c.2603G>A p.G868E | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100880677; called by muse, mutect2, varscan2
- COL6A1 | c.2087G>A p.W696* | Nonsense Mutation (SNP) | VAF 6/10 reads (60%) | catalogued as COSV100720517; called by muse, mutect2
- COL6A1 | c.2088G>A p.W696* | Nonsense Mutation (SNP) | VAF 6/10 reads (60%) | catalogued as rs1341291007, COSV100720519; called by muse, mutect2
- COL6A3 | c.6512G>A p.G2171E | Missense Mutation (SNP) | VAF 119/188 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99802214; called by muse, mutect2, varscan2
- COL6A6 | c.5494C>T p.P1832S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.019); catalogued as COSV62028356; called by muse, mutect2, varscan2
- COL7A1 | c.5224C>T p.P1742S | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.118); catalogued as COSV100097953; called by muse, mutect2, varscan2
- COL9A2 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.857); catalogued as rs868338361, COSV101025800; called by muse, mutect2, varscan2
- COL9A3 | c.1732G>A p.G578R | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV100102527; called by muse, mutect2
- COL9A3 | c.1733G>A p.G578E | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100102528; called by muse, mutect2
- COLQ | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as rs1432176251, COSV101082598; called by muse, mutect2, varscan2
- COPG1 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 81/227 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs1373945411, COSV100136026; called by muse, mutect2, varscan2
- COPS3 | c.922C>T p.Q308* | Nonsense Mutation (SNP) | VAF 40/103 reads (39%) | catalogued as COSV99253930; called by muse, mutect2, varscan2
- COQ9 | c.245A>T p.Y82F | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as COSV99346045; called by muse, mutect2, varscan2
- CPA3 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs772998748, COSV99936443; called by muse, mutect2, varscan2
- CPA6 | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99915082; called by muse, mutect2, varscan2
- CPAMD8 | c.2737C>T p.P913S (on ENST00000651564; = p.P866S on NM_015692.5) | Missense Mutation (SNP) | VAF 68/186 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV101488628; called by muse, mutect2, varscan2
- CPB1 | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.947); catalogued as rs775486211, COSV99294587; called by muse, mutect2, varscan2
- CPLANE1 | c.9574C>T p.H3192Y | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV57063475; called by muse, mutect2
- CPN2 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60472411; called by muse, mutect2, varscan2
- CPQ | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99615444; called by muse, mutect2, varscan2
- CPSF2 | c.2050G>A p.G684R | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.868); catalogued as rs1051749868, COSV100103168; called by muse, mutect2, varscan2
- CRAMP1 | c.2768G>A p.R923Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746567769, COSV99246494; called by muse, mutect2
- CREBBP | c.5008C>T p.L1670F | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV99272697; called by muse, mutect2, varscan2
- CREBRF | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.075); catalogued as COSV99756513; called by muse, mutect2, varscan2
- CRTAC1 | c.1241G>A p.G414E | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as COSV100084907; called by muse, mutect2, varscan2
- CRYM | c.631A>C p.I211L | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV99561973; called by muse, mutect2, varscan2
- CSH2 | c.588G>A p.M196I | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.387); catalogued as rs755978056, COSV100400366, COSV61080260; called by muse, mutect2, varscan2
- CSKMT | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as rs759348507, COSV100649148, COSV63472944; called by muse, mutect2, varscan2
- CSMD1 | c.10096T>A p.L3366I (on ENST00000520002; = p.L3365I on NM_033225.6) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.174); catalogued as COSV100154706; called by muse, mutect2
- CSMD1 | c.6542C>T p.P2181L (on ENST00000520002; = p.P2180L on NM_033225.6) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.998); catalogued as COSV100154709; called by muse, mutect2, varscan2
- CSMD1 | c.6367C>A p.H2123N (on ENST00000520002; = p.H2122N on NM_033225.6) | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.396); catalogued as COSV100154711; called by muse, mutect2, varscan2
- CSMD1 | c.3293T>G p.L1098R (on ENST00000520002; = p.L1097R on NM_033225.6) | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100154713; called by muse, mutect2, varscan2
- CSMD3 | c.2434C>T p.Q812* (on ENST00000297405 / NM_001363185.1; = p.Q708* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 27/76 reads (36%) | catalogued as COSV52116928; called by muse, mutect2, varscan2
- CSMD3 | c.1933G>A p.E645K (on ENST00000297405 / NM_001363185.1; = p.E541K on NM_052900.3) | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs780733307, COSV52256469, COSV99852540; called by muse, varscan2
- CSMD3 | c.412T>C p.F138L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV99850748; called by muse, varscan2
- CSNK1A1L | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs775219612, COSV65789844; called by muse, mutect2, varscan2
- CSPG4 | c.3781C>T p.Q1261* | Nonsense Mutation (SNP) | VAF 66/141 reads (47%) | catalogued as rs1335116934, COSV100414264; called by muse, mutect2, varscan2
- CTBP2 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100456124, COSV100457072; called by muse, mutect2, varscan2
- CTNNA2 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 30/86 reads (35%) | catalogued as COSV100559341, COSV58180946; called by muse, mutect2, varscan2
- CTNNA3 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs1360112371, COSV65559601, COSV65567164; called by muse, mutect2, varscan2
- CTTNBP2 | c.2393C>T p.S798L | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as COSV50390171; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1747C>T p.P583S | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99600315; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1748C>T p.P583L | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99600317; called by muse, mutect2, varscan2
- CUX1 | c.2765C>T p.P922L | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV99473416; called by muse, mutect2, varscan2
- CUX2 | c.1198G>T p.E400* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as COSV99920995; called by muse, mutect2, varscan2
- CYLC1 | c.1226C>T p.S409F | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100255615; called by muse, mutect2, varscan2
- CYP11A1 | c.1237-1G>A p.X413_splice | Splice Site (SNP) | VAF 17/40 reads (43%) | catalogued as COSV99166279; called by muse, mutect2, varscan2
- CYP11A1 | c.809G>A p.W270* | Nonsense Mutation (SNP) | VAF 99/241 reads (41%) | catalogued as COSV99166281; called by muse, mutect2, varscan2
- CYP2J2 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100968146; called by muse, mutect2, varscan2
- CYP4A22 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99595382; called by muse, varscan2
- CYP4F2 | c.1379C>T p.P460L | Missense Mutation (SNP) | VAF 68/190 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55616418; called by muse, mutect2, varscan2
- CYP4F2 | c.939A>T p.L313F | Missense Mutation (SNP) | VAF 99/247 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99171176; called by muse, mutect2, varscan2
- DAB2 | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV100298447; called by muse, mutect2, varscan2
- DACH1 | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV100499475; called by muse, mutect2, varscan2
- DACH2 | c.173G>A p.G58D | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.066); catalogued as rs1369194138, COSV100914050; called by muse, mutect2, varscan2
- DACH2 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | catalogued as COSV100914051; called by muse, mutect2, varscan2
- DACT1 | c.2050G>A p.E684K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60020811; called by muse, mutect2, varscan2
- DAG1 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV58186306; called by muse, mutect2, varscan2
- DBF4B | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 38/129 reads (29%) | catalogued as rs779155219, COSV59260369; called by muse, mutect2, varscan2
- DBNDD1 | c.469G>A p.E157K (on ENST00000002501 / NM_001042610.3; = p.E177K on NM_024043.3) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV99136602; called by muse, mutect2, varscan2
- DBP | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99709258, COSV99709687; called by muse, mutect2, varscan2
- DCAF1 | c.4367C>T p.P1456L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated, low confidence (0.5); PolyPhen possibly damaging (0.525); catalogued as COSV100244320, COSV100245044; called by muse, mutect2, varscan2
- DCAF1 | c.4366C>T p.P1456S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.325); catalogued as COSV100245045; called by muse, mutect2, varscan2
- DCAF12L1 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765423775, COSV64421797; called by muse, mutect2, varscan2
- DCD | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.069); catalogued as COSV99514148; called by muse, mutect2, varscan2
- DCD | c.205G>A p.G69S | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.069); catalogued as COSV53201813, COSV99514149; called by muse, mutect2, varscan2
- DCDC1 | c.4028C>T p.P1343L (on ENST00000597505 / NM_001367979.1; = p.P450L on NM_020869.3) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100338862, COSV100338879; called by muse, mutect2, varscan2
- DCHS1 | c.3412G>A p.G1138R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100202702; called by muse, mutect2, varscan2
- DDR2 | c.2331G>T p.L777F | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100906937; called by muse, mutect2, varscan2
- DDX46 | c.2665C>T p.P889S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.053); catalogued as COSV100844939; called by muse, mutect2, varscan2
- DDX53 | c.1637G>A p.R546K | Missense Mutation (SNP) | VAF 65/151 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.153); catalogued as rs1314947944, COSV100029143; called by muse, mutect2, varscan2
- DDX6 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99870735; called by muse, mutect2, varscan2
- DEDD2 | c.496G>T p.G166C | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.249); catalogued as COSV100260394; called by muse, mutect2, varscan2
- DENND2A | c.3019C>T p.H1007Y | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as rs1437020313, COSV99327172; called by muse, varscan2
- DENND3 | c.791T>A p.F264Y | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.677); catalogued as COSV99371851; called by muse, mutect2, varscan2
- DENND4C | c.5057G>A p.R1686Q (on ENST00000434457 / NM_001330640.2; = p.R1637Q on NM_017925.7) | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV63010276; called by muse, mutect2, varscan2
- DENND5A | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV100065339; called by muse, mutect2, varscan2
- DENND5B | c.1801G>A p.V601I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as rs1319449432, COSV100172365; called by muse, mutect2, varscan2
- DEUP1 | c.102G>A p.M34I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99977733; called by muse, mutect2, varscan2
- DGAT2L6 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100284172; called by muse, mutect2, varscan2
- DGKQ | c.2777C>T p.T926I | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99298302; called by muse, mutect2, varscan2
- DHFR2 | c.212G>T p.R71I | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775609912, COSV58936660; called by muse, mutect2, varscan2
- DHX37 | c.3062C>T p.P1021L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1353194025, COSV100439581; called by muse, mutect2, varscan2
- DHX37 | c.3061C>T p.P1021S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100439582; called by muse, mutect2, varscan2
- DHX8 | c.1826C>T p.S609F | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV52251148; called by muse, mutect2, varscan2
- DIAPH2 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100235878; called by muse, mutect2, varscan2
- DICER1 | c.4850T>A p.L1617H | Missense Mutation (SNP) | VAF 146/362 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.159); catalogued as COSV100602639; called by muse, mutect2, varscan2
- DICER1 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100602563, COSV100602640; called by muse, mutect2, varscan2
- DIP2B | c.2857G>A p.G953S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); catalogued as COSV99999617; called by muse, mutect2, varscan2
- DIP2B | c.4454G>A p.R1485Q | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56586635; called by muse, mutect2, varscan2
- DISP1 | c.4378C>T p.P1460S | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as COSV52656036, COSV99452395; called by muse, mutect2, varscan2
- DISP1 | c.4379C>T p.P1460L | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.035); catalogued as COSV99452396; called by muse, mutect2, varscan2
- DISP2 | c.2531G>A p.W844* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV99140000, COSV99140657; called by muse, mutect2, varscan2
- DLEC1 | c.2051G>A p.R684K | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV57302137; called by muse, mutect2, varscan2
- DLG5 | c.2132C>T p.S711F | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64947748; called by muse, mutect2, varscan2
- DLL3 | c.686G>A p.G229D | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753887634, COSV99219589; called by muse, mutect2, varscan2
- DLST | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.978); catalogued as COSV99472193; called by muse, mutect2, varscan2
- DMXL1 | c.6716C>T p.S2239F | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV100225194, COSV99075339; called by muse, mutect2, varscan2
- DNAH11 | c.3343C>A p.P1115T | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV100181313; called by muse, mutect2, varscan2
- DNAH11 | c.3344C>T p.P1115L | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV100181317; called by muse, mutect2, varscan2
- DNAH11 | c.5134G>A p.E1712K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV100179873, COSV100181319; called by muse, mutect2, varscan2
- DNAH11 | c.8333T>G p.M2778R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV100179555, COSV100181322; called by muse, mutect2, varscan2
- DNAH17 | c.9524G>A p.G3175E | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as COSV67752569; called by muse, mutect2, varscan2
- DNAH2 | c.3134G>A p.G1045E | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101209642; called by muse, mutect2, varscan2
- DNAH2 | c.10229G>A p.G3410E | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.098); catalogued as COSV101209643; called by muse, mutect2, varscan2
- DNAH3 | c.4388C>T p.A1463V | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99771207; called by muse, mutect2, varscan2
- DNAH5 | c.5993G>A p.G1998E | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54243321; called by muse, mutect2, varscan2
- DNAH8 | c.10510G>A p.D3504N | Missense Mutation (SNP) | VAF 50/89 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs755050080, COSV100547405; called by muse, mutect2, varscan2
- DNAH9 | c.1087C>T p.Q363* | Nonsense Mutation (SNP) | VAF 33/94 reads (35%) | catalogued as rs758130208, COSV99308695; called by muse, mutect2, varscan2
- DNAJC2 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.956); catalogued as COSV99972019; called by muse, mutect2, varscan2
- DNAL1 | c.218G>A p.R73K | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100225690, COSV100225930; called by muse, mutect2
- DNASE2 | c.460G>A p.G154R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs747962653, COSV99263835; called by muse, mutect2, varscan2
- DNMT3B | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.05); catalogued as COSV99145057; called by muse, mutect2, varscan2
- DOCK1 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.92); catalogued as COSV99733406; called by muse, mutect2, varscan2
- DOCK11 | c.1512+1G>A p.X504_splice | Splice Site (SNP) | VAF 22/56 reads (39%) | catalogued as COSV99354983; called by muse, mutect2, varscan2
- DOCK8 | c.3452C>T p.S1151F | Missense Mutation (SNP) | VAF 104/132 reads (79%) | SIFT tolerated (0.7); PolyPhen benign (0.066); catalogued as COSV101209953; called by muse, mutect2, varscan2
- DOK5 | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52826166; called by muse, mutect2, varscan2
- DOT1L | c.2273C>T p.P758L | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.038); catalogued as rs776898259, COSV67113184; called by muse, mutect2, varscan2
- DPEP1 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.517); catalogued as COSV99878742; called by muse, mutect2, varscan2
- DPP10 | c.2191C>T p.H731Y | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59697538; called by muse, mutect2, varscan2
- DPP4 | c.196C>T p.H66Y | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100859150; called by muse, mutect2, varscan2
- DPP9 | c.700G>A p.D234N (on ENST00000598800; = p.D263N on NM_139159.5) | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV99506602; called by muse, varscan2
- DPRX | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs761892759, COSV64949245; called by muse, mutect2, varscan2
- DPYSL3 | c.302C>T p.T101I | Missense Mutation (SNP) | VAF 86/201 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100575429; called by muse, mutect2, varscan2
- DRAXIN | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99611031; called by muse, mutect2, varscan2
- DRC1 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV99719270; called by muse, mutect2, varscan2
- DST | c.20063C>T p.T6688I (on ENST00000361203 / NM_001374722.1; = p.T4385I on NM_015548.5) | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99759071; called by muse, mutect2, varscan2
- DST | c.3688C>T p.H1230Y (on ENST00000361203 / NM_001374722.1; = p.H904Y on NM_001723.6) | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs868279643, COSV55000633; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DTD1 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as rs1347411922, COSV66283131; called by muse, mutect2, varscan2
- DUOX1 | c.2081C>T p.S694F | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100368588; called by muse, mutect2, varscan2
- DUSP7 | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV99623720; called by muse, varscan2
- DVL3 | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV99491043; called by muse, mutect2, varscan2
- DYNC1I2 | c.712T>G p.S238A | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99784410; called by muse, mutect2, varscan2
- DYNC2I1 | c.2362A>T p.T788S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as COSV101337740; called by muse, mutect2, varscan2
- E2F4 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1227247778, COSV100104363; called by muse, mutect2, varscan2
- EBF1 | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.009); catalogued as COSV100566766, COSV58196788; called by muse, mutect2, varscan2
- EDC4 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV100739356; called by muse, mutect2, varscan2
- EEF2 | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV100501044; called by muse, mutect2, varscan2
- EFCAB6 | c.2207C>T p.P736L | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV99414636; called by muse, mutect2, varscan2
- EFHB | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.001); catalogued as COSV99860364; called by muse, mutect2, varscan2
- EGFLAM | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); catalogued as COSV59312072; called by muse, mutect2, varscan2
- EGFLAM | c.1084T>A p.Y362N | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100380895, COSV100381007; called by muse, mutect2, varscan2
- EHHADH | c.2123C>T p.P708L | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99213400; called by muse, mutect2, varscan2
- EHHADH | c.2122C>T p.P708S | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99213402; called by muse, mutect2, varscan2
- EIF3L | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV101094746; called by muse, mutect2, varscan2
- EIF6 | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 90/206 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV99864202; called by muse, mutect2, varscan2
- ELAPOR1 | c.1859C>T p.S620F | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as COSV100884496; called by muse, mutect2, varscan2
- ELAPOR2 | c.2317G>A p.A773T (on ENST00000450689 / NM_001142749.3; = p.A606T on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.09); catalogued as COSV99789495; called by muse, mutect2, varscan2
- ELK3 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV99957840; called by muse, mutect2, varscan2
- ELMO1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV60306554, COSV60329494; called by muse, mutect2, varscan2
- ELN | c.1600G>A p.V534M | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.281); catalogued as rs1394004060, COSV99333298; called by muse, mutect2, varscan2
- ELOA2 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV99798449; called by muse, mutect2, varscan2
- ELP4 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 34/100 reads (34%) | catalogued as COSV99541391; called by muse, mutect2, varscan2
- EMC2 | c.768T>G p.Y256* | Nonsense Mutation (SNP) | VAF 28/66 reads (42%) | catalogued as COSV99624634; called by muse, mutect2, varscan2
- EMID1 | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV100469379; called by muse, varscan2
- EMID1 | c.403+1G>A p.X135_splice | Splice Site (SNP) | VAF 25/69 reads (36%) | catalogued as rs1450573102, COSV100469381; called by muse, mutect2, varscan2
- EMILIN1 | c.1733G>A p.G578E | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV99566626; called by muse, mutect2, varscan2
- EMSY | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 70/179 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58263000; called by muse, mutect2, varscan2
- ENPP2 | c.2183G>A p.R728K (on ENST00000075322 / NM_001040092.3; = p.R780K on NM_006209.5) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV99307242, COSV99309545; called by muse, mutect2, varscan2
- ENPP6 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99699179; called by muse, mutect2, varscan2
- EP400 | c.1951C>T p.P651S | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.007); catalogued as COSV100202518; called by muse, mutect2, varscan2
- EP400 | c.5398C>T p.P1800S | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57788963; called by muse, mutect2, varscan2
- EP400 | c.8548C>T p.R2850W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57770982; called by muse, mutect2, varscan2
- EPB41L1 | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52436790; called by muse, mutect2, varscan2
- EPHA10 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1268474857, COSV60404587; called by muse, mutect2, varscan2
- EPHB1 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 74/205 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV67665633, COSV67669839; called by muse, mutect2, varscan2
- EPPK1 | c.4636G>A p.E1546K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as rs191532254; called by muse, mutect2, varscan2
- ERBB3 | c.2473C>T p.L825F | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99918092; called by muse, mutect2, varscan2
- ERC1 | c.1603G>A p.E535K (on ENST00000360905 / NM_178040.4; = p.E507K on NM_178039.4) | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100706894; called by muse, mutect2, varscan2
- ERICH3 | c.3262G>A p.D1088N | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.12); catalogued as rs1336419480, COSV100446058; called by muse, mutect2, varscan2
- ESYT3 | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV101272776; called by muse, mutect2, varscan2
- ETV1 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as COSV54151406, COSV99624759; called by muse, mutect2, varscan2
- ETV3L | c.467C>A p.P156H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs745957498, COSV101485629; called by muse, mutect2, varscan2
- EVC | c.1994C>T p.S665L | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs375340438; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EVPL | c.5830C>T p.L1944F | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56914558; called by muse, mutect2, varscan2
- EXD1 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV59255171; called by muse, mutect2, varscan2
- EXOC4 | c.909G>C p.L303F | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.795); catalogued as rs1365946196, COSV99556073; called by muse, mutect2, varscan2
- EXOC5 | c.1907C>T p.A636V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV100567315; called by muse, mutect2, varscan2
- EYA1 | c.1735G>T p.D579Y | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD122914, COSV100380452; called by muse, mutect2
- EZH1 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 37/95 reads (39%) | catalogued as COSV101331468; called by muse, mutect2, varscan2
- F2 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as COSV100319742; called by muse, mutect2, varscan2
- F5 | c.4459C>T p.L1487F | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as COSV100889281; called by muse, mutect2, varscan2
- F8 | c.4246C>T p.P1416S | Missense Mutation (SNP) | VAF 100/197 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV100812091; called by muse, mutect2, varscan2
- F8 | c.690A>C p.E230D | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.419); catalogued as COSV100812092; called by muse, mutect2, varscan2
- FABP1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 94/270 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99861015; called by muse, mutect2, varscan2
- FABP4 | c.27G>A p.W9* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as COSV99808668; called by muse, mutect2, varscan2
- FAH | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99930608; called by muse, mutect2, varscan2
- FAM131B | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.025); catalogued as rs778571208, COSV58368129; called by muse, mutect2, varscan2
- FAM135B | c.3340A>G p.S1114G | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV99428435; called by muse, varscan2
- FAM135B | c.3286T>C p.Y1096H | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.32); catalogued as rs1008410739, COSV99428437; called by muse, varscan2
- FAM13B | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50368480; called by muse, mutect2, varscan2
- FAM229B | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.998); catalogued as rs782240107, COSV100898206; called by muse, mutect2, varscan2
- FAM24B | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV100159035; called by muse, mutect2, varscan2
- FAM47A | c.2093G>A p.W698* | Nonsense Mutation (SNP) | VAF 43/121 reads (36%) | catalogued as COSV100650117; called by muse, mutect2, varscan2
- FAM47A | c.1468A>G p.S490G | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.135); catalogued as COSV100650118; called by muse, varscan2
- FAM47A | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.034); catalogued as COSV100650120; called by muse, varscan2
- FAM47A | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.647); catalogued as COSV100650121, COSV60493685, COSV60499619; called by muse, varscan2
- FAM47B | c.445G>C p.V149L | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.629); catalogued as COSV100264701, COSV61453052; called by muse, mutect2, varscan2
- FAM47C | c.2009C>T p.P670L | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs1395373719, COSV100792998; called by muse, varscan2
- FAM53C | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.987); catalogued as COSV99524568; called by muse, mutect2, varscan2
- FAM78A | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 97/118 reads (82%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV99908546; called by muse, mutect2, varscan2
- FAM78B | c.389A>G p.K130R | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.452); catalogued as COSV100597884; called by muse, mutect2, varscan2
- FAM83A | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.596); catalogued as COSV52687472; called by muse, mutect2, varscan2
- FANCD2 | c.1873C>T p.P625S | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.86); catalogued as rs747225209, COSV55035371; called by muse, mutect2, varscan2
- FARP1 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 78/221 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV100132309; called by muse, mutect2, varscan2
- FARP1 | c.1064G>A p.G355E | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.966); catalogued as COSV100132311; called by muse, mutect2, varscan2
- FARP1 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV100132314; called by muse, mutect2, varscan2
- FARP1 | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs780123613, COSV60334189; called by muse, mutect2, varscan2
- FAT2 | c.12289G>T p.A4097S | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV99944374; called by muse, mutect2, varscan2
- FAT2 | c.3302C>G p.S1101C | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV99944377; called by muse, mutect2, varscan2
- FAT2 | c.1910C>T p.S637F | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV99944379; called by muse, mutect2, varscan2
- FAT3 | c.230G>A p.W77* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as COSV53111202, COSV99972075; called by muse, mutect2, varscan2
- FAT3 | c.231G>A p.W77* | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | catalogued as COSV53085490, COSV99971708; called by muse, mutect2, varscan2
- FAT3 | c.953G>A p.G318E | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs1241267664, COSV99972086; called by muse, mutect2, varscan2
- FAT3 | c.4823G>A p.G1608E | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99972091; called by muse, mutect2, varscan2
- FAT4 | c.2671C>T p.P891S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101272919; called by muse, mutect2, varscan2
- FAT4 | c.2672C>T p.P891L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101272920; called by muse, mutect2, varscan2
- FAT4 | c.8363C>T p.P2788L | Missense Mutation (SNP) | VAF 67/141 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267600011, COSV100630494; called by muse, mutect2, varscan2
- FAT4 | c.10211C>T p.P3404L | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100630496; called by muse, mutect2, varscan2
- FAT4 | c.13621G>A p.E4541K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.013); catalogued as rs775440091, COSV100630497; called by muse, mutect2, varscan2
- FBN3 | c.2779G>A p.G927R | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.522); catalogued as COSV99560609, COSV99562016; called by muse, mutect2, varscan2
- FBXO34 | c.1595T>C p.V532A | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100572222; called by muse, mutect2, varscan2
- FCRL4 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.034); catalogued as COSV99620593; called by muse, mutect2, varscan2
- FCRL5 | c.299T>C p.F100S | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV100709415; called by muse, mutect2, varscan2
- FDFT1 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55042750, COSV99594931; called by muse, mutect2, varscan2
- FERD3L | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.077); catalogued as rs959722211, COSV99285146; called by muse, mutect2, varscan2
- FGFR3 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs373470718, COSV53395496; called by muse, mutect2, varscan2
- FGFR4 | c.1073G>A p.W358* | Nonsense Mutation (SNP) | VAF 17/36 reads (47%) | catalogued as COSV99451115; called by muse, mutect2, varscan2
- FGFR4 | c.1074G>A p.W358* | Nonsense Mutation (SNP) | VAF 17/35 reads (49%) | catalogued as rs1168418391, COSV99451116; called by muse, mutect2, varscan2
- FHOD3 | c.3968C>T p.S1323F (on ENST00000359247 / NM_001281739.3; = p.S1340F on NM_025135.5) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV57171514; called by muse, mutect2, varscan2
- FKRP | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV100586738; called by muse, mutect2
- FLNA | c.4660G>A p.G1554R | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100775362; called by muse, mutect2, varscan2
- FLNA | c.2459C>T p.A820V | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as COSV100775364; called by muse, mutect2, varscan2
- FLT1 | c.1327C>T p.L443F | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV99169376; called by muse, mutect2, varscan2
- FMN2 | c.3632C>T p.P1211L | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100147619; called by muse, mutect2, varscan2
- FMOD | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 12/21 reads (57%) | catalogued as COSV100724653; called by muse, mutect2, varscan2
- FMOD | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV61609782; called by muse, mutect2, varscan2
- FMR1NB | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.948); catalogued as COSV100975636; called by muse, mutect2, varscan2
- FNBP1 | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 107/160 reads (67%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV100852841; called by muse, mutect2, varscan2
- FNDC11 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as COSV100918848; called by muse, mutect2, varscan2
- FNDC4 | c.650G>A p.R217K | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.117); catalogued as COSV53022287, COSV99254104; called by muse, mutect2, varscan2
- FNTA | c.1105A>T p.T369S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100172713; called by muse, mutect2, varscan2
- FNTA | c.1106C>T p.T369I | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV100172715; called by muse, mutect2, varscan2
- FOSL2 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV53103621; called by muse, mutect2, varscan2
- FOXK1 | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 95/189 reads (50%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.497); catalogued as COSV100195769; called by muse, mutect2, varscan2
- FOXN3 | c.1376C>T p.S459F (on ENST00000261302; = p.S437F on NM_005197.4) | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV54307508; called by muse, mutect2, varscan2
- FOXO4 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100447088; called by muse, mutect2, varscan2
- FPR1 | c.602G>C p.R201T | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.065); catalogued as COSV100494122; called by muse, mutect2, varscan2
- FPR1 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100494241; called by muse, mutect2
- FPR3 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as COSV59329921; called by muse, mutect2, varscan2
- FREM1 | c.2915C>T p.P972L | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV101085666; called by muse, mutect2, varscan2
- FREM1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.08); PolyPhen benign (0.132); catalogued as COSV101085669; called by muse, mutect2, varscan2
- FRMPD2 | c.3472G>A p.E1158K | Missense Mutation (SNP) | VAF 65/81 reads (80%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV59724690; called by muse, mutect2, varscan2
- FRMPD2 | c.1196A>T p.E399V | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100564289; called by muse, varscan2
- FRYL | c.5819A>T p.N1940I | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.109); catalogued as COSV99978459; called by muse, mutect2, varscan2
- FSCB | c.995A>T p.E332V | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100469995; called by muse, mutect2, varscan2
- FSHR | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 125/316 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.135); catalogued as COSV100438285; called by muse, mutect2, varscan2
- FYB1 | c.1859C>T p.P620L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.796); catalogued as rs770043614, COSV100686561; called by muse, mutect2, varscan2
- FYCO1 | c.2651C>T p.S884F | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.192); catalogued as COSV99946382; called by muse, mutect2, varscan2
- GAB4 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 12/22 reads (55%) | PolyPhen benign (0.009); catalogued as rs375162045; called by muse, mutect2, varscan2
- GABRA2 | c.887T>A p.L296Q | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100734825; called by muse, mutect2, varscan2
- GABRA3 | c.1020G>C p.W340C | Missense Mutation (SNP) | VAF 52/97 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100943500; called by muse, mutect2, varscan2
- GABRA6 | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs377497663, COSV50890037; called by muse, mutect2, varscan2
- GABRB3 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs1468792368, COSV100162331; called by muse, mutect2, varscan2
- GALR3 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.092); catalogued as COSV99968084; called by muse, mutect2, varscan2
- GANC | c.2218G>A p.G740R | Missense Mutation (SNP) | VAF 12/39 reads (31%) | PolyPhen probably damaging (0.998); catalogued as rs1411389665, COSV100531314; called by muse, mutect2, varscan2
- GAR1 | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56992826, COSV99902037; called by muse, mutect2, varscan2
- GAS2L1 | c.1966C>T p.P656S | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.354); catalogued as rs754054977, COSV53332248, COSV99329754; called by muse, mutect2
- GAS2L1 | c.1967C>T p.P656L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.026); catalogued as rs755054331, COSV53331926; called by muse, mutect2
- GBF1 | c.3991G>A p.G1331S (on ENST00000369983 / NM_001377137.1; = p.G1330S on NM_004193.3) | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.166); catalogued as COSV100890715; called by muse, mutect2, varscan2
- GBP5 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100600188; called by muse, mutect2, varscan2
- GBP6 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV65012791; called by muse, mutect2, varscan2
- GCN1 | c.1823T>A p.L608Q | Missense Mutation (SNP) | VAF 116/230 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100326201, COSV56109468; called by muse, mutect2, varscan2
- GDF2 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs782304973; called by muse, mutect2, varscan2
- GDF2 | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs141580368; called by muse, mutect2, varscan2
- GFPT2 | c.1675-1G>A p.X559_splice | Splice Site (SNP) | VAF 46/125 reads (37%) | catalogued as COSV99518195; called by muse, mutect2, varscan2
- GFRA1 | c.527C>T p.T176I | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as rs1323105417, COSV100816282, COSV62602714, COSV62608747; called by muse, mutect2, varscan2
- GGN | c.1103G>A p.G368E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV99287729; called by muse, mutect2
- GGN | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs943922359, COSV53058001; called by muse, mutect2
- GJA10 | c.326G>A p.R109K | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.029); catalogued as COSV101005463; called by muse, mutect2, varscan2
- GK2 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1321996211, COSV62626188; called by muse, mutect2, varscan2
- GLDC | c.2963G>A p.R988Q | Missense Mutation (SNP) | VAF 64/82 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749512886, COSV100394700; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLI3 | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV101229966; called by muse, mutect2, varscan2
- GLUD2 | c.1457C>T p.P486L | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV100047157; called by muse, mutect2, varscan2
- GLYR1 | c.841G>A p.G281R | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100424613; called by muse, mutect2, varscan2
- GMEB2 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.376); catalogued as COSV99823913; called by muse, mutect2
- GNAT1 | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.05); catalogued as COSV99138107; called by muse, mutect2, varscan2
- GOLGA3 | c.370C>T p.L124F | Missense Mutation (SNP) | VAF 66/114 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs748262825, COSV99213223; called by muse, mutect2, varscan2
- GPAM | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1282132340, COSV62081180; called by muse, mutect2, varscan2
- GPATCH3 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); catalogued as COSV100658934; called by muse, mutect2
- GPC6 | c.878-1G>A p.X293_splice | Splice Site (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100990181; called by muse, mutect2, varscan2
- GPKOW | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.498); catalogued as COSV99332837; called by muse, mutect2, varscan2
- GPR39 | c.1211G>A p.R404K | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.053); catalogued as rs779259145, COSV100258787, COSV100258811; called by muse, mutect2, varscan2
- GPR50 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV54436845, COSV54438339; called by muse, mutect2, varscan2
- GPR50 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV54438356, COSV54438852; called by muse, mutect2, varscan2
- GPRASP1 | c.2741G>A p.G914E | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV100851100; called by muse, mutect2, varscan2
- GPRASP2 | c.1702C>T p.R568* | Nonsense Mutation (SNP) | VAF 70/171 reads (41%) | catalogued as COSV59991156; called by muse, mutect2, varscan2
- GPRC5A | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 70/182 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV99185665; called by muse, mutect2, varscan2
- GPSM3 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs769669212, COSV100900727; called by muse, mutect2, varscan2
- GRAMD1A | c.1573C>T p.H525Y | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); catalogued as COSV100526465; called by muse, mutect2, varscan2
- GRAMD1B | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.84); catalogued as rs1198666415, COSV100455359; called by muse, mutect2, varscan2
- GREB1 | c.488A>G p.K163R | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs775736833, COSV99303986; called by muse, mutect2, varscan2
- GRIA3 | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 87/182 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52067487; called by muse, mutect2, varscan2
- GRIA4 | c.1076G>A p.G359E | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56879536, COSV56898445; called by muse, mutect2, varscan2
- GRIA4 | c.2273C>G p.T758R | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99235172; called by muse, mutect2, varscan2
- GRID1 | c.2128C>T p.R710W | Missense Mutation (SNP) | VAF 129/276 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs377669879; called by muse, mutect2, varscan2
- GRIK1 | c.1062G>A p.W354* | Nonsense Mutation (SNP) | VAF 27/42 reads (64%) | catalogued as COSV100518158; called by muse, mutect2, varscan2
- GRIK1 | c.1061G>A p.W354* | Nonsense Mutation (SNP) | VAF 26/41 reads (63%) | catalogued as COSV100518163; called by muse, mutect2, varscan2
- GRIN1 | c.1864+1G>A p.X622_splice | Splice Site (SNP) | VAF 13/14 reads (93%) | catalogued as COSV100160808; called by muse, mutect2, varscan2
- GRIN3A | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs767070992, COSV62450727; called by muse, mutect2, varscan2
- GRIPAP1 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs782108488, COSV100904419; called by muse, mutect2, varscan2
- GRM2 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.86); PolyPhen benign (0.024); catalogued as COSV99623245; called by muse, mutect2, varscan2
- GUCY1A2 | c.1336C>T p.H446Y | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56488271; called by muse, mutect2, varscan2
- GUCY2D | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 98/134 reads (73%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV54696474; called by muse, mutect2, varscan2
- GUCY2D | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 96/133 reads (72%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs1350341897, COSV99644367; called by muse, mutect2, varscan2
- GUCY2F | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99484933; called by muse, mutect2, varscan2
- GUSB | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as rs1347468886, COSV100512594; called by muse, mutect2, varscan2
- GXYLT1 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.513); catalogued as rs75740340, COSV99789204; called by muse, mutect2, varscan2
- GYS1 | c.120G>A p.V40= | Splice Region (SNP) | VAF 72/193 reads (37%) | catalogued as COSV99621291; called by muse, mutect2, varscan2
- H4C5 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as rs572454026, COSV100748082; called by muse, mutect2, varscan2
- HABP2 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100668121; called by muse, mutect2, varscan2
- HACE1 | c.1241G>A p.G414E | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs781687827, COSV99494395; called by muse, mutect2, varscan2
- HAUS5 | c.1675C>T p.Q559* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV99178856; called by muse, mutect2, varscan2
- HAX1 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV99672556; called by muse, mutect2, varscan2
- HAX1 | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99672558; called by muse, mutect2, varscan2
- HBG2 | c.361A>T p.K121* | Nonsense Mutation (SNP) | VAF 29/86 reads (34%) | catalogued as COSV100400722; called by muse, mutect2, varscan2
- HBP1 | c.623C>G p.P208R | Missense Mutation (SNP) | VAF 65/145 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99753668; called by muse, mutect2, varscan2
- HCAR3 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV100811859; called by muse, mutect2, varscan2
- HCFC1 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100130076; called by muse, mutect2, varscan2
- HCFC1 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100130079; called by muse, mutect2, varscan2
- HCRTR1 | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs755298261, COSV101036340; called by muse, mutect2, varscan2
- HCRTR2 | c.1309G>A p.G437R | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.999); catalogued as COSV100904704; called by muse, mutect2, varscan2
- HDAC2 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV100892773, COSV100892808; called by muse, mutect2, varscan2
- HECTD4 | c.9173C>T p.A3058V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.82); PolyPhen benign (0.031); catalogued as COSV101108415; called by muse, mutect2, varscan2
- HECTD4 | c.7933G>A p.D2645N | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as COSV101108416; called by muse, mutect2, varscan2
- HECW2 | c.2411G>A p.R804K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.525); catalogued as COSV99649350; called by muse, mutect2, varscan2
- HELLS | c.1324C>T p.Q442* | Nonsense Mutation (SNP) | VAF 30/77 reads (39%) | catalogued as COSV99492476; called by muse, mutect2, varscan2
- HELZ | c.3502C>T p.L1168F | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.564); catalogued as COSV100699112, COSV62381342; called by muse, mutect2, varscan2
- HELZ2 | c.6235C>T p.P2079S (on ENST00000467148 / NM_001037335.2; = p.P1510S on NM_033405.3) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV101427634; called by muse, mutect2, varscan2
- HELZ2 | c.802G>A p.G268R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs772810619, COSV100915733; called by muse, mutect2, varscan2
- HEPH | c.878A>T p.H293L (on ENST00000343002; = p.H26L on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV100295913; called by muse, mutect2, varscan2
- HEPH | c.1248T>A p.F416L (on ENST00000343002; = p.F149L on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV100295915; called by muse, mutect2, varscan2
- HEPHL1 | c.2134C>T p.Q712* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as COSV100244551, COSV59894773; called by muse, varscan2
- HEPHL1 | c.2201C>T p.T734I | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.059); catalogued as rs776079231, COSV100244554; called by muse, varscan2
- HERPUD2 | c.608A>T p.Y203F | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV100258170; called by muse, mutect2, varscan2
- HEY2 | c.1001T>C p.V334A | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV100856443; called by muse, mutect2
- HFM1 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV54028173; called by muse, mutect2, varscan2
- HIVEP2 | c.3599C>T p.P1200L | Missense Mutation (SNP) | VAF 84/137 reads (61%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.722); catalogued as COSV99176419; called by muse, mutect2, varscan2
- HIVEP3 | c.4384C>T p.L1462F | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99914255; called by muse, mutect2, varscan2
- HLTF | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV100027196; called by muse, mutect2, varscan2
- HMBOX1 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.407); catalogued as COSV99816604; called by muse, mutect2, varscan2
- HMCN1 | c.6583C>T p.P2195S | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1476907390, COSV99637256; called by muse, mutect2, varscan2
- HMCN1 | c.11411C>T p.P3804L | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99637260; called by muse, mutect2, varscan2
- HMCN1 | c.11956G>A p.E3986K | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as rs866315314, COSV99637266; called by muse, mutect2, varscan2
- HMOX1 | c.593G>A p.R198K | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV99330893; called by muse, mutect2, varscan2
- HNF4A | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as rs1204164924, COSV57380922; called by muse, mutect2, varscan2
- HNF4G | c.1090C>T p.H364Y (on ENST00000354370 / NM_001330561.2; = p.H411Y on NM_004133.5) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated, low confidence (0.61); PolyPhen possibly damaging (0.487); catalogued as COSV62971901; called by muse, mutect2, varscan2
- HNRNPAB | c.916G>A p.G306S | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.731); catalogued as rs369576001; called by muse, mutect2, varscan2
- HNRNPH2 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 75/165 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as COSV54508037; called by muse, mutect2, varscan2
- HOMEZ | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV100664215, COSV62536786; called by muse, mutect2, varscan2
- HOXB13 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs372121677; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HOXB3 | c.722T>G p.M241R | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100290849; called by muse, mutect2, varscan2
- HOXB4 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.84); PolyPhen benign (0.051); catalogued as rs773856875, COSV100203875; called by muse, mutect2, varscan2
- HPS5 | c.860C>T p.S287F (on ENST00000349215 / NM_181507.2; = p.S173F on NM_007216.4) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV100834485; called by muse, mutect2, varscan2
- HRAS | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 37/111 reads (33%) | catalogued as COSV99531014; called by muse, mutect2, varscan2
- HRNR | c.2168C>T p.S723F | Missense Mutation (SNP) | VAF 91/187 reads (49%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.795); catalogued as rs756043881, COSV100914031; called by muse, mutect2, varscan2
- HSD17B4 | c.230C>T p.S77F (on ENST00000414835 / NM_001199291.3; = p.S52F on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99820254; called by muse, mutect2, varscan2
- HSD3B1 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV52489806; called by muse, mutect2, varscan2
- HSPA1L | c.984G>A p.M328I | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as COSV65149133; called by muse, mutect2, varscan2
- HSPG2 | c.6856C>T p.P2286S | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs1382315251, COSV101021385; called by muse, mutect2, varscan2
- HSPG2 | c.2176C>T p.H726Y | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.824); catalogued as COSV101021074, COSV101021387; called by muse, mutect2, varscan2
- HUWE1 | c.13006C>T p.P4336S | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV99474723; called by muse, mutect2, varscan2
- HYAL3 | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs782168795, COSV100269879, COSV60186351; called by muse, mutect2, varscan2
- ICAM2 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.216); catalogued as COSV56743436, COSV99857059; called by muse, mutect2, varscan2
- IDUA | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as rs1258131965, COSV99926548; called by muse, mutect2
- IFI27L2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 33/94 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as rs376561007; called by muse, mutect2, varscan2
- IFI30 | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.996); catalogued as rs766567273, COSV101325438; called by muse, mutect2, varscan2
- IFIT3 | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99261104; called by muse, mutect2, varscan2
- IFIT3 | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1441886057, COSV51078431; called by muse, mutect2, varscan2
- IFIT5 | c.1165C>T p.H389Y | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV100877979; called by mutect2, varscan2
- IFNA10 | c.299G>A p.W100* | Nonsense Mutation (SNP) | VAF 55/82 reads (67%) | catalogued as COSV99497637; called by muse, mutect2, varscan2
- IFT80 | c.2083C>T p.L695F | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100425196; called by muse, mutect2, varscan2
- IGDCC3 | c.299A>C p.H100P | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as COSV100031600; called by muse, mutect2, varscan2
- IGF1 | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 226/300 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV61031622, COSV61033552; called by muse, mutect2, varscan2
- IGKV1-27 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as rs778478221; called by muse, mutect2, varscan2
- IGKV3-7 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs775561089; called by muse, mutect2, varscan2
- IGSF21 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV52127636; called by muse, mutect2, varscan2
- IGSF5 | c.1060C>T p.L354F | Missense Mutation (SNP) | VAF 56/86 reads (65%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV101012125, COSV101012148; called by muse, mutect2, varscan2
- IL13RA2 | c.1075A>G p.T359A | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99683430; called by muse, mutect2, varscan2
- IL18RAP | c.1250G>A p.W417* | Nonsense Mutation (SNP) | VAF 41/109 reads (38%) | catalogued as COSV99962503; called by muse, mutect2, varscan2
- IL18RAP | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV99962504; called by muse, mutect2, varscan2
- IL1RAPL1 | c.580A>T p.I194F | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as COSV100151338; called by muse, mutect2, varscan2
- IL1RAPL2 | c.126G>A p.M42I | Missense Mutation (SNP) | VAF 62/119 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as COSV100782165; called by muse, mutect2, varscan2
- IL1RAPL2 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.454); catalogued as COSV61165123; called by muse, mutect2, varscan2
- IL1RL1 | c.771A>C p.K257N | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV99294624; called by muse, mutect2, varscan2
- IL6ST | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100411095; called by muse, mutect2, varscan2
- ILVBL | c.985C>T p.H329Y | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); catalogued as COSV99655191; called by muse, mutect2, varscan2
- INO80 | c.2020C>T p.R674W | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370606160; called by muse, mutect2, varscan2
- INSL6 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 86/106 reads (81%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV101068546, COSV67563566; called by muse, mutect2, varscan2
- INSYN1 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.085); catalogued as rs1482190029, COSV101138828; called by muse, mutect2, varscan2
- IPO13 | c.1189C>T p.L397F | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV100961364; called by muse, mutect2, varscan2
- IQCE | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.453); catalogued as COSV100383821; called by muse, mutect2, varscan2
- IQCH | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 18/43 reads (42%) | catalogued as rs1384083082, COSV100246419; called by muse, mutect2, varscan2
- IQSEC3 | c.1157C>T p.S386F (on ENST00000538872 / NM_001170738.2; = p.S83F on NM_015232.1) | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs1221691608, COSV100407780, COSV58288922; called by muse, mutect2, varscan2
- IQUB | c.2345A>T p.K782M | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV100227415; called by muse, mutect2, varscan2
- IQUB | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV61243286; called by muse, mutect2, varscan2
- IRAG1 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101351832; called by muse, mutect2, varscan2
- IRAK1 | c.955C>T p.L319F | Missense Mutation (SNP) | VAF 66/197 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100318564; called by muse, mutect2, varscan2
- IRF1 | c.547C>T p.L183= | Splice Region (SNP) | VAF 24/87 reads (28%) | catalogued as rs768359746, COSV99810795; called by muse, mutect2, varscan2
- IRF2BP1 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs866805087, COSV56192959; called by muse, mutect2, varscan2
- IRS4 | c.1783G>A p.G595R | Missense Mutation (SNP) | VAF 116/334 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV100929812; called by muse, mutect2, varscan2
- IRS4 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as rs1294535708, COSV100929813; called by muse, mutect2, varscan2
- IRX4 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1453473481, COSV51473443; called by muse, mutect2, varscan2
- IRX4 | c.322T>G p.S108A | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99182583; called by muse, mutect2, varscan2
- ITGA10 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs782502872, COSV100995070; called by muse, mutect2, varscan2
- ITGA11 | c.1648C>T p.R550* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as rs1384365052, COSV59875355; called by muse, mutect2, varscan2
- ITGA2B | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99289340; called by muse, mutect2, varscan2
- ITGA5 | c.2386G>A p.G796S | Missense Mutation (SNP) | VAF 67/171 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs374858882, COSV53218843; called by muse, mutect2, varscan2
2,037 further variants in this file (1,077 protein-altering or splice-affecting, 905 silent, 55 other) are not listed here.
